CCDI case PBBVBI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1ae36007-7bd7-450e-8661-60f21f970ff1

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 4.9 years (1,806 days).

Biospecimens (2 samples)
- Sample 0DII31: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DII41: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
